Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A6VV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A6VV-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, infiltrating duct NOS
8500/3

C6CF
② Breast NOS C50.9

path
② Breast, medullary C50.8

gnd 2/25/13

Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Sentinel lymph node, right axilla, biopsy: One negative lymph node (0/1).
- B. Breast, right, mastectomy: Invasive ductal carcinoma, grade 3, size 4.5 cm in greatest dimension, with ductal carcinoma in-situ, grade 3 with necrosis; negative margins of excision.
- C. Breast, left, mastectomy: Focal atypical ductal hyperplasia; negative margins of excision.
- D. Lymph nodes, right axilla, regional resection: Four negative lymph nodes (0/4).

Microscopic Description:

Invasive carcinoma:

Histologic type: Ductal
Histologic grade: 3
Overall grade: 9/9
Architectural score: 3
Nuclear score: 3
Mitotic score: 3
Greatest dimension (pT): Size 4.5 cm in greatest dimension
Specimen margins: Negative
Vessel invasion: Not identified
Nipple (Paget's): Negative
Invasion of skin or chest wall: Negative

Ductal carcinoma in situ:

Histologic pattern: Solid, cribriform
Nuclear grade: 3
Central necrosis: Present
% DCIS of total tumor (if mixed): 10%
Extensive intraductal component (present/absent): Absent
Specimen margins: Negative
Calcification: Present

Description of non-tumorous breast: Fibrocystic changes including apocrine metaplasia with cyst formation

Comments: Prior biopsy site identified. Focal atypical ductal hyperplasia, with partial involvement of a duct by a cribriform cell population, is present within the left breast.

Distant metastasis (pM): Unknown

Lymph nodes:

Number of positive nodes of total: 0 of 5
Size of largest metastasis: N/A
Extracapsular extension (present/absent): N/A
pN: pN0

Prognostic markers: See previous core biopsy at

Specimen

- A. Right sentinel node (axillary)
- B. Right breast tumor at 12:00
- C. Left breast tissue
- D. Right axillary content

[page 2 of 2]
Clinical Information

Right breast, tumor at 12:00, large mass + for carcinoma right breast

Intraoperative Consultation

^ One negative lymph node.

Gross Description

A. Received unfixed for frozen section, labeled sentinel node right, is a lymph node that is fat-replaced and 2 x 1.5 x 1.5 cm, entirely frozen in 3 blocks.

B. Received unfixed for tissue procurement, labeled right breast, is a 1444 gram right breast that is unoriented and 23 cm medial to lateral, 22 cm superior to inferior, and 4.5 cm anterior to posterior. There is an anterior black skin ellipse, 20 x 5 cm with 5 cm areola and 1.5 cm nipple. There is a tan-gritty tumor at 12:00, up to 4.5 cm in greatest dimension, and close to the anterior margin. Sections as follows: 1-6 continuous tumor, 7/8 tumor, 9 tumor, 10 RUQ random, 11 RLQ random, 12 LLQ random, 13 LUQ random, 14 nipple, 15 areola

C. Received unfixed, labeled left breast, is a portion of fibroadipose breast tissue and skin that is 818 grams and 26 x 17 x 5 cm. Skin is darkly pigmented, and without focal lesions. Sectioning through the breast tissue shows no mass lesions. Representative sections in 8 blocks.

D. Received unfixed, labeled right axillary content, is a 9 x 7 x 2 cm portion of fatty nodal tissue. Lymph nodes are identified: 1 one node, 2 two nodes, 3 one node.

Electronically Signed By:

1. AA Discrepancy		✓
Qualification: Primary Listed		

Source: NCI Genomic Data Commons file cd0f0570-732a-412b-b63b-5503758b8f6a (TCGA-A7-A6VV.C26EAF0E-202B-4F3E-9E59-3395A1BFCAB8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).